Somatic mutation profile of tumor specimen TCGA-C5-A8YT-01A (aliquot TCGA-C5-A8YT-01A-11D-A37N-09) from TCGA case TCGA-C5-A8YT, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IB1; Tumor grade: G3; Age at diagnosis: 36.3 years (13,253 days).
Specimen TCGA-C5-A8YT-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 65cb6de7-7e62-45db-8341-5c90693513cc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-C5-A8YT-10A (Blood Derived Normal), aliquot TCGA-C5-A8YT-10A-01D-A37N-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9a314ff2-d386-4415-aa9f-dc7ffb26d282

The open-access MAF lists 2 somatic variants for this specimen: 1 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PRICKLE2 | c.2457C>A p.D819E (on ENST00000295902; = p.D763E on NM_198859.4) | Missense Mutation (SNP) | VAF 3/32 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV55768083, COSV99898091; called by muse, mutect2
- MUC2 | chr11:1097397 C>T | 3'Flank (SNP) | VAF 4/20 reads (20%) | catalogued as rs1198159316; called by mutect2, varscan2
